Gene-level copy-number profile of tumor specimen HCM-CSHL-0248-C19-01A from HCMI case HCM-CSHL-0248-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 53.4 years (19,501 days).
Specimen HCM-CSHL-0248-C19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c946ee14-5ea8-45a5-8ee1-5d1cbe86afac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0248-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/ed8ab9c9-c665-471c-9da7-d220db667b8a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 643; copy number 2: 5,453; copy number 3: 10,019; copy number 4: 27,954; copy number 5: 5,259; copy number 6: 6,832; copy number 7: 863; copy number 8: 1,347; copy number 23: 10; copy number 30: 11.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,560,047–18,568,790, 2 genes: CR383656.7, CR383656.13.
- chr15:24,162,754–24,240,192, 3 genes: PWRN2, AC087463.1, AC087463.2.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 21 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 30 (within-gene range 4–30): AL627309.1.
- chr1:131,025–522,928, 20 genes, copy number 23–30: CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.

Autosomal genes at a single copy (total copy number 1): 637. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
